Surgical pathology report (de-identified scan), TCGA case TCGA-2Z-A9JR, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma), tissue source site Moffitt Cancer Center, specimen TCGA-2Z-A9JR-01A (Primary Tumor).

[page 1 of 2]
Pathology Report

Final Diagnosis

- A. RIGHT KIDNEY, PARTIAL NEPHRECTOMY:
Renal cell carcinoma, papillary type II. See Key Pathologic Findings.
Surgical margin, free of malignancy.
Pathologic stage: pT1a NX MX.
- B. DEEP MARGIN:
Renal parenchyma, no evidence of malignancy.

I, _____ the attending pathologist, personally reviewed all slides and / or materials and rendered the final diagnosis. Electronically signed out by _____

Key Pathological Findings

A: Kidney Resection
PROCEDURE:
Partial nephrectomy
SPECIMEN LATERALITY:
Right
TUMOR SIZE (largest tumor if multiple):
Dimension: 2.8 cm
MACROSCOPIC EXTENT OF TUMOR:
Tumor limited to kidney
HISTOLOGIC TYPE:
Papillary renal cell carcinoma
SARCOMATOID FEATURES:
Not identified
TUMOR NECROSIS:
< 5%
HISTOLOGIC GRADE (Fuhrman Nuclear Grade):
II-III, predominantly III
MICROSCOPIC TUMOR EXTENSION:
Tumor limited to kidney
MARGINS:
Margins uninvolved by carcinoma
ADRENAL GLAND:
Not present
PERINEURAL INVASION:
Absent
ANGIOLYMPHATIC INVASION:
Absent
LYMPH-VASCULAR INVASION:
Absent

ICD O.3
Carcinoma, papillary renal cell
8260/3
Site: R Kidney NOS
C64.9
JW 4/28/14

[page 2 of 2]
PRIMARY TUMOR (pT):

pT1a: Tumor 4 cm or less in greatest dimension, limited to the kidney

REGIONAL LYMPH NODES (pN):

pNX: Regional lymph nodes cannot be assessed

DISTANT METASTASIS (pM):

pMX

Specimen(s) Received

- A RIGHT PARTIAL NEPHRECTOMY FS
B DEEP MARGIN FS

Clinical History

RIGHT RENAL MASS

Preoperative Diagnosis

RIGHT RENAL MASS

Intraoperative Consultation

FSA1. RIGHT PARTIAL NEPHRECTOMY:
Renal cell carcinoma.

FSB1. DEEP MARGIN:
Negative for carcinoma.

Comment: This frozen section diagnosis/result was communicated to and acknowledged by Dr.

I, _____ M.D., have performed the intraoperative consultation(s) and issued the above diagnosis.

Gross Description

A. Specimen A is received fresh labeled "right partial nephrectomy ink is margin." The specimen consists of a partial nephrectomy measuring 3.9 x 2.8 x 2.9 cm weighing 13.1 g. The specimen is oriented according to the surgeon's designation and is inked as follows:

Parenchymal resection margin inked: Blue
Renal capsule is inked: Black

On sectioning the specimen reveals an irregular ill-defined rubbery intraparenchymal solid tumor which measures 2.8 x 2.5 x 2.4 cm. The tumor bulges the renal capsule and extends to within 0.3 cm of the closest parenchymal resection margin. Cut surface of the tumor is pale yellow to tan brown focally hemorrhagic. Representative section of the tumor in relation to the closest parenchymal resection margin is submitted for frozen section as FSA1. Representative sections of the specimen are submitted to the Tissue Procurement Laboratory. Additional sections of the specimen are submitted in 8 cassettes as follows:

A2-A9: Tumor with adjacent and involved renal parenchyma and overlying renal capsule.

B. Specimen B received fresh labeled "deep margin, ink is margin." The specimen consists of an irregular oriented fragment of renal parenchyma measuring 1.7 x 1.2 x 0.7 cm. The specimen is oriented according to the surgeon's designation and the new parenchymal resection margin is re-inked black. The specimen is serially sectioned and is submitted entirely for frozen section as FSB1.

Source: NCI Genomic Data Commons file 6214f574-2153-4596-a731-436fca95d172 (TCGA-2Z-A9JR.7C79CF14-EF5F-45BF-A84B-14B97F1AC3DE.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).